Somatic mutation profile of tumor specimen TARGET-10-PANVKF-09A (aliquot TARGET-10-PANVKF-09A-01D) from TARGET case TARGET-10-PANVKF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,440 days).
Specimen TARGET-10-PANVKF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c81b8424-cb2d-4805-bbba-381d93bd6c51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVKF-14A (Bone Marrow Normal), aliquot TARGET-10-PANVKF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc32f1e3-7a4f-45cc-8a17-fd0f961fe76e

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, Intron 1, RNA 1, In Frame Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 7/103 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2
- ACE | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs746314800, COSV52012716; called by muse, mutect2, varscan2
- ADAM12 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763997822; called by muse, mutect2
- ATF7IP | c.1706G>C p.R569P | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53774760, COSV53777006; called by muse, mutect2, varscan2
- LRRC72 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145598091, COSV69130441; called by muse, mutect2, varscan2
- TCF25 | c.393A>C p.K131N | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs772673723, COSV54524826; called by muse, mutect2, varscan2
- TFAP2C | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs150059207, COSV99571385; called by mutect2, varscan2
- ATF7IP | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- ATP11A | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- NOBOX | c.1261T>C p.S421P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NXF1 | c.637A>C p.K213Q | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- OR5T3 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SDHAF4 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A6 | c.1883G>A p.C628Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX10 | c.64_66del p.K22del | In Frame Del (DEL) | VAF 8/32 reads (25%) | called by pindel, varscan2
- EPB41L2 | c.1986G>A p.P662= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs376910072; called by muse, mutect2, varscan2
- TAF1L | c.5031G>A p.T1677= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs763903524, COSV54264307; called by muse, mutect2, varscan2
- TEX15 | c.3672C>T p.D1224= (on ENST00000256246; = p.D1607= on NM_001350162.2) | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs372369352; called by muse, mutect2, varscan2
- WDR87 | c.7779C>A p.S2593= | Silent (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- FLNB | c.5555-114C>T | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as rs1298084387; called by muse, mutect2, varscan2
- POLE3 | c.*83G>T | 3'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2
- PPATP1 | n.1108_1109del | RNA (DEL) | VAF 27/68 reads (40%) | called by pindel, varscan2
- TRAPPC1 | c.-31C>T | 5'UTR (SNP) | VAF 9/59 reads (15%) | catalogued as rs531253495; called by muse, mutect2, varscan2
